Surgical pathology report (de-identified scan), TCGA case TCGA-R8-A6YH, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MD Anderson, specimen TCGA-R8-A6YH-01A (Primary Tumor).

(178.0cm 86.0kg BSA: 2.06m²)

Accession:
Specimen Date/Time:

DIAGNOSIS

(A) BRAIN RESECTION DESIGNATED RIGHT FRONTAL:
ANAPLASTIC ASTROCYTOMA (WHO Grade III.) See comment.

ICD-O-3
Astrocytoma, grade III
9401/3
Site Brain, supratentorial NOS
271.0
QW 8/11/13

Entire report and diagnosis completed by

COMMENT

Scattered mitotic figures are identified, but there is no microvascular proliferation or necrosis. Immunohistochemistry for GFAP confirms the fibrillary nature of the tumor. Immunohistochemistry with the MIB-1 antibody (Ki-67 antigen) shows a tumor labeling index of 5.1% in one section of the anaplastic astrocytoma (1400 cells counted.) Controls stain appropriately.

GROSS DESCRIPTION

(A) RIGHT FRONTAL BRAIN TUMOR - A single resection specimen of brain measuring 8.5 x 7.0 x 6.0 cm. The specimen is fleshy, gray-tan to gray-white and diffusely firm. In one area a multilocular cyst measuring up to 2.0 cm is present within the tumor. In another area, there is a 4.0 cm cyst filled with a dark brown blood clot. The specimen is photographed. Portions are sent for special studies. Tissue is reserved for possible electron microscopy. The remainder is submitted.

SECTION CODE: A1, frozen section; A2-A6, permanent sections.

*FS/DX: ANAPLASTIC GLIOMA.

CLINICAL HISTORY

History of previous limited biopsy showing low-grade astrocytoma

SNOMED CODES

T-A2000, M-94013

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by

—END OF REPORT—

Source: NCI Genomic Data Commons file ebfb31b3-e8b7-4397-87be-3be608392b4c (TCGA-R8-A6YH.911537EB-E3CE-4D30-B3A2-90932D94A4DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).